Somatic mutation profile of tumor specimen C3L-00977-02 (aliquot CPT0169640006) from CPTAC case C3L-00977, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 56.5 years (20,653 days).
Specimen C3L-00977-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d46d4a9-a3a8-499b-a901-3d5f5123557b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00977-31 (Blood Derived Normal), aliquot CPT0167150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58cb2ca2-9bc1-44fe-87d5-351a3df0144e

The open-access MAF lists 143 somatic variants for this specimen: 95 protein-altering or splice-affecting, 30 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 30, Intron 10, Frame Shift Ins 4, 5'UTR 4, Frame Shift Del 3, In Frame Del 2, Splice Site 2, 3'UTR 1, 5'Flank 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.6100G>A p.G2034R | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121912844, CM970378, CM980409; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 116/523 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 469/1084 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 92/350 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58685695; called by muse, mutect2, varscan2
- ANK2 | c.2770G>T p.D924Y | Missense Mutation (SNP) | VAF 137/747 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs770636500, COSV100004064; called by muse, mutect2, varscan2
- AP3B2 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 110/582 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1310381151; called by muse, mutect2, varscan2
- ATP4A | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 96/496 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs776928883; called by muse, mutect2, varscan2
- CYP4F2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 85/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769787930; called by muse, mutect2, varscan2
- DNAH7 | c.11271G>C p.L3757F | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56753895; called by muse, mutect2
- DNAH7 | c.6014A>G p.N2005S | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.402); catalogued as rs768010727; called by muse, mutect2, varscan2
- DSPP | c.1448A>T p.N483I | Missense Mutation (SNP) | VAF 172/949 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV56815529; called by muse, mutect2, varscan2
- DUS3L | c.1485C>T p.F495= | Splice Region (SNP) | VAF 41/195 reads (21%) | catalogued as rs886376950; called by muse, mutect2, varscan2
- ESS2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 45/216 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV50082540; called by muse, mutect2, varscan2
- FOXG1 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 23/456 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV57396560; called by muse, mutect2
- GABRB2 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 94/448 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs777778428, COSV50905153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT2 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1389631551; called by muse, mutect2, varscan2
- GDF6 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 203/1401 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408241682, COSV54624952, COSV99748436; called by muse, mutect2, varscan2
- GREB1 | c.581T>A p.V194D | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs756031034; called by muse, mutect2, varscan2
- GSPT1 | c.825C>A p.F275L (on ENST00000420576 / NM_001130007.2; = p.F413L on NM_002094.4) | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV70452768; called by muse, mutect2, varscan2
- IMPDH1 | c.631G>A p.V211I (on ENST00000470772 / NM_001142573.2; = p.V297I on NM_000883.4) | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as rs375104715, COSV58315641; called by muse, mutect2, varscan2
- MDN1 | c.3830G>A p.R1277Q | Missense Mutation (SNP) | VAF 45/377 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1206783600; called by muse, mutect2, varscan2
- MYH4 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 76/479 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV55120617; called by muse, mutect2, varscan2
- MYO5A | c.3130C>T p.R1044C | Missense Mutation (SNP) | VAF 149/727 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs763440706, COSV62559539; called by muse, mutect2, varscan2
- NAA15 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as CD135251, COSV56717517; called by muse, mutect2, varscan2
- OR4K1 | c.716C>A p.T239K | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53460141; called by muse, mutect2, varscan2
- OTOF | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs765368301, COSV55521339; called by muse, mutect2, varscan2
- PARP10 | c.1420C>A p.L474I | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV57297694; called by muse, mutect2, varscan2
- PPP1R10 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 112/566 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV64740734; called by muse, mutect2, varscan2
- PRX | c.4004G>A p.R1335Q | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as CM145156, COSV52523337; called by muse, mutect2, varscan2
- SLC47A2 | c.792_794del p.L265del | In Frame Del (DEL) | VAF 49/316 reads (16%) | catalogued as rs1462938123; called by mutect2, pindel, varscan2
- SMTN | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs371605791, COSV100295044, COSV60778817; called by muse, mutect2
- SNX22 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs920319213; called by muse, mutect2, varscan2
- TAS1R3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 95/485 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs144635443, COSV100229675; called by muse, mutect2, varscan2
- TMEM59L | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 110/505 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV99449935; called by muse, mutect2, varscan2
- VPS13D | c.1456A>G p.M486V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs771684037; called by muse, mutect2, varscan2
- VRTN | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs756291711, COSV56439091; called by muse, mutect2, varscan2
- WNT7B | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 96/457 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1047376841; called by muse, mutect2, varscan2
- ZNF626 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555769202; called by muse, mutect2, varscan2
- ABL2 | c.6del p.Q3Sfs*87 | Frame Shift Del (DEL) | VAF 28/116 reads (24%) | called by mutect2, pindel, varscan2
- ADAM22 | c.1409G>C p.G470A | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD17 | c.5438C>T p.S1813L | Missense Mutation (SNP) | VAF 81/517 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AP3B2 | c.951C>A p.S317R | Missense Mutation (SNP) | VAF 113/583 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ASPM | c.7007G>A p.R2336K | Missense Mutation (SNP) | VAF 73/377 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- CCDC168 | c.20039A>T p.K6680M | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CFHR3 | c.110A>T p.N37I | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- CNTNAP2 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 135/623 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CREB3L3 | c.1222A>T p.T408S | Missense Mutation (SNP) | VAF 125/674 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.2652G>C p.W884C (on ENST00000297405 / NM_001363185.1; = p.W780C on NM_052900.3) | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.3599-2A>T p.X1200_splice | Splice Site (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- DSTYK | c.507del p.Q170Sfs*4 | Frame Shift Del (DEL) | VAF 65/413 reads (16%) | called by mutect2, pindel, varscan2
- EPHA7 | c.2661dup p.G888Wfs*12 | Frame Shift Ins (INS) | VAF 27/159 reads (17%) | called by mutect2, pindel, varscan2
- FBN3 | c.4970A>G p.Y1657C | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- FXR2 | c.82-2A>G p.X28_splice | Splice Site (SNP) | VAF 86/180 reads (48%) | called by muse, mutect2, varscan2
- GCAT | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HIVEP2 | c.1551A>T p.K517N | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNJ6 | c.616del p.S206Pfs*5 | Frame Shift Del (DEL) | VAF 50/263 reads (19%) | called by mutect2, pindel, varscan2
- KMT2E | c.87A>T p.E29D | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KMT2E | c.4172dup p.N1391Kfs*17 | Frame Shift Ins (INS) | VAF 49/314 reads (16%) | called by mutect2, pindel, varscan2
- LLGL1 | c.299A>T p.H100L | Missense Mutation (SNP) | VAF 102/395 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- LMOD1 | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYPD5 | c.72A>T p.Q24H | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD6 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MED11 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MTMR10 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- MYO18B | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 14/387 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- NCAPD3 | c.2595G>T p.Q865H | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NEBL | c.1757C>T p.T586I | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- NFE2L2 | c.802dup p.V268Gfs*16 | Frame Shift Ins (INS) | VAF 39/299 reads (13%) | called by mutect2, pindel, varscan2
- NPC1 | c.587A>G p.K196R | Missense Mutation (SNP) | VAF 96/427 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NUP214 | c.5848G>A p.G1950R | Missense Mutation (SNP) | VAF 119/311 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH10 | c.3086A>C p.Y1029S | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- PCNX4 | c.984C>G p.N328K (on ENST00000406854 / NM_001330177.2; = p.N94K on NM_022495.5) | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- PIF1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 217/1004 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- PIGG | c.1966G>T p.A656S (on ENST00000453061 / NM_001127178.3; = p.A648S on NM_017733.4) | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PITX2 | c.229_234del p.E77_D78del (on ENST00000354925 / NM_001204397.1; = p.E84_D85del on NM_000325.6) | In Frame Del (DEL) | VAF 38/267 reads (14%) | called by mutect2, pindel, varscan2
- PNLIPRP2 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PPP2CB | c.331dup p.I111Nfs*21 | Frame Shift Ins (INS) | VAF 33/183 reads (18%) | called by mutect2, pindel, varscan2
- PPP2R2A | c.1318T>A p.Y440N | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PSMB1 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PSMB2 | c.225G>T p.L75F | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- RBM25 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 120/558 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, varscan2
- RRP15 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SCGN | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A13 | c.1414G>T p.G472* | Nonsense Mutation (SNP) | VAF 28/206 reads (14%) | called by muse, mutect2, varscan2
- SMTNL1 | c.137C>G p.P46R | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.287); called by muse, mutect2
- SSU72P8 | c.26C>A p.A9D | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- THOC2 | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TMEM141 | c.306G>T p.R102S | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNKS | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TRIM14 | c.824C>G p.T275R | Missense Mutation (SNP) | VAF 91/663 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- WEE1 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XK | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFHX4 | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 76/403 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF683 | c.368T>A p.F123Y | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF711 | c.2177T>C p.I726T | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADGRF1 | c.1557C>T p.F519= | Silent (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- AGO4 | c.2517G>A p.R839= | Silent (SNP) | VAF 49/296 reads (17%) | catalogued as rs756039230; called by muse, mutect2, varscan2
- AKAP3 | c.652T>C p.L218= | Silent (SNP) | VAF 7/190 reads (4%) | called by muse, mutect2
- ANO5 | c.2595C>A p.I865= | Silent (SNP) | VAF 26/290 reads (9%) | called by muse, mutect2
- ATP8B3 | c.999C>T p.N333= | Silent (SNP) | VAF 26/676 reads (4%) | called by muse, mutect2
- ATRAID | c.195G>T p.T65= (on ENST00000611786; = p.T10= on NM_001170795.3) | Silent (SNP) | VAF 136/890 reads (15%) | called by muse, mutect2, varscan2
- CD163L1 | c.507G>A p.E169= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as rs572276485, COSV100549969; called by muse, mutect2, varscan2
- COPS7B | c.468C>T p.F156= | Silent (SNP) | VAF 112/560 reads (20%) | called by muse, mutect2, varscan2
- DENND5B | c.1578G>A p.Q526= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as rs953856368; called by muse, mutect2
- DMD | c.3846A>G p.L1282= | Silent (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- GOLGA4 | c.5325G>A p.E1775= | Silent (SNP) | VAF 55/273 reads (20%) | called by muse, mutect2, varscan2
- KIAA1549 | c.4602G>A p.K1534= | Silent (SNP) | VAF 102/469 reads (22%) | catalogued as COSV99650861; called by muse, mutect2, varscan2
- LONRF2 | c.1593G>A p.L531= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2
- MACF1 | c.7701A>G p.K2567= | Silent (SNP) | VAF 37/167 reads (22%) | catalogued as COSV99246467; called by muse, mutect2, varscan2
- NOP53 | c.270C>T p.D90= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as rs980429337; called by muse, mutect2, varscan2
- OGDHL | c.1197C>T p.A399= | Silent (SNP) | VAF 74/357 reads (21%) | catalogued as rs139847941; called by muse, mutect2, varscan2
- OR9G1 | c.645C>G p.A215= | Silent (SNP) | VAF 26/632 reads (4%) | catalogued as COSV56454735; called by muse, mutect2
- PAX3 | c.1134C>T p.N378= | Silent (SNP) | VAF 112/483 reads (23%) | called by muse, mutect2, varscan2
- PPM1D | c.180C>T p.G60= | Silent (SNP) | VAF 104/456 reads (23%) | called by muse, mutect2, varscan2
- PSG8 | c.57G>A p.L19= | Silent (SNP) | VAF 94/543 reads (17%) | called by muse, mutect2, varscan2
- RAI1 | c.1512G>A p.T504= | Silent (SNP) | VAF 86/357 reads (24%) | catalogued as rs750119897; called by muse, mutect2, varscan2
- RBM22 | c.159A>T p.T53= | Silent (SNP) | VAF 42/194 reads (22%) | catalogued as COSV52271549; called by muse, mutect2, varscan2
- RFC4 | c.498C>T p.T166= | Silent (SNP) | VAF 72/188 reads (38%) | called by muse, mutect2, varscan2
- RP1 | c.1245T>C p.S415= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as rs1166426667; called by muse, mutect2, varscan2
- SCUBE1 | c.1332G>A p.S444= | Silent (SNP) | VAF 60/359 reads (17%) | catalogued as rs145976658; called by muse, mutect2, varscan2
- SFR1 | c.9G>A p.E3= | Silent (SNP) | VAF 58/289 reads (20%) | called by muse, mutect2, varscan2
- SPINK5 | c.2760A>C p.R920= | Silent (SNP) | VAF 85/526 reads (16%) | called by muse, mutect2, varscan2
- TENM2 | c.435C>A p.S145= | Silent (SNP) | VAF 131/844 reads (16%) | called by muse, mutect2, varscan2
- USH2A | c.14850C>T p.N4950= | Silent (SNP) | VAF 26/673 reads (4%) | called by muse, mutect2
- ZFP90 | c.1140C>T p.S380= | Silent (SNP) | VAF 42/247 reads (17%) | called by muse, mutect2, varscan2
- DMRTB1 | c.*14C>T | 3'UTR (SNP) | VAF 70/317 reads (22%) | called by muse, mutect2, varscan2
- EMX1 | chr2:72916864 G>T | 5'Flank (SNP) | VAF 160/881 reads (18%) | called by muse, mutect2, varscan2
- ETFA | c.665-633G>A | Intron (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.1514-472C>T | Intron (SNP) | VAF 86/580 reads (15%) | catalogued as rs754020553; called by muse, mutect2, varscan2
- IGHV1-69 | c.-4C>T | 5'UTR (SNP) | VAF 14/194 reads (7%) | catalogued as rs1555594444; called by muse, mutect2
- LYSMD3 | c.-108C>A | 5'UTR (SNP) | VAF 89/451 reads (20%) | called by muse, mutect2, varscan2
- MARF1 | c.4627-288T>C | Intron (SNP) | VAF 55/249 reads (22%) | called by muse, mutect2, varscan2
- MOK | chr14:102226340 T>C | 3'Flank (SNP) | VAF 86/335 reads (26%) | catalogued as rs1312457361; called by muse, mutect2, varscan2
- PDE4B | c.281+74281T>C | Intron (SNP) | VAF 48/206 reads (23%) | catalogued as rs529480644; called by muse, mutect2, varscan2
- PDSS2 | c.630+9571G>T | Intron (SNP) | VAF 30/228 reads (13%) | catalogued as rs905226986; called by muse, mutect2, varscan2
- RAPGEF5 | c.295+1770C>A | Intron (SNP) | VAF 140/510 reads (27%) | called by muse, mutect2, varscan2
- RPS24 | c.390+640C>G | Intron (SNP) | VAF 30/198 reads (15%) | catalogued as rs770872382; called by muse, mutect2, varscan2
- SNORD115-8 | n.39A>T | RNA (SNP) | VAF 126/526 reads (24%) | called by muse, mutect2, varscan2
- STK19 | c.567+103A>T | Intron (SNP) | VAF 90/437 reads (21%) | called by muse, mutect2, varscan2
- TPD52L1 | c.387-22_387-18del | Intron (DEL) | VAF 48/207 reads (23%) | called by mutect2, pindel, varscan2
- WIPI2 | c.-38G>T | 5'UTR (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- ZNF74 | c.-406C>T | 5'UTR (SNP) | VAF 32/191 reads (17%) | catalogued as rs1428296286; called by muse, mutect2, varscan2
- ZNF76 | c.432+82C>G | Intron (SNP) | VAF 71/545 reads (13%) | called by muse, mutect2, varscan2
